Somatic mutation profile of tumor specimen TCGA-EB-A1NK-01A (aliquot TCGA-EB-A1NK-01A-11D-A196-08) from TCGA case TCGA-EB-A1NK, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 48.1 years (17,569 days).
Specimen TCGA-EB-A1NK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f17570c3-948b-4897-b246-b112f0587028.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A1NK-10A (Blood Derived Normal), aliquot TCGA-EB-A1NK-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39d5b681-82a5-4242-bdd3-45b4634bc51c

The open-access MAF lists 175 somatic variants for this specimen: 110 protein-altering or splice-affecting, 59 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 59, Nonsense Mutation 7, Splice Region 3, Intron 3, Frame Shift Del 2, Splice Site 2, RNA 2, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 41/145 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, varscan2
- ADAMTS17 | c.2414C>T p.T805I | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as COSV51492182; called by muse, mutect2, varscan2
- ADAMTS8 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961445; called by muse, mutect2
- AHR | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV54121637; called by muse, mutect2, varscan2
- AKAP11 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV50301533; called by muse, mutect2, varscan2
- ARID2 | c.93-1G>A p.X31_splice | Splice Site (SNP) | VAF 9/15 reads (60%) | catalogued as COSV57600718, COSV99044005; called by muse, mutect2, varscan2
- ARID2 | c.93G>A p.G31= | Splice Region (SNP) | VAF 9/15 reads (60%) | catalogued as rs1488076478, COSV100536832; called by muse, mutect2, varscan2
- ATAD2 | c.3019C>T p.R1007* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV54879522; called by muse, mutect2, varscan2
- ATP11A | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs141227366; called by muse, mutect2, varscan2
- BPGM | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV61326056; called by muse, mutect2, varscan2
- BPTF | c.5875C>T p.R1959* | Nonsense Mutation (SNP) | VAF 39/138 reads (28%) | catalogued as COSV58845683; called by muse, mutect2, varscan2
- C8orf74 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV58755432, COSV58755514; called by muse, mutect2
- CACNA1B | c.4975G>A p.E1659K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745458852, COSV53124332, COSV53145854; called by muse, mutect2, varscan2
- CACNA2D3 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55575949; called by muse, mutect2, varscan2
- CALHM4 | c.931G>A p.E311K (on ENST00000368596 / NM_001366078.1; = p.E125K on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100888897; called by muse, mutect2, varscan2
- CARD11 | c.687C>T p.I229= | Splice Region (SNP) | VAF 56/118 reads (47%) | catalogued as rs369930171; called by muse, mutect2, varscan2
- CCDC172 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV100319840, COSV60939594; called by muse, mutect2, varscan2
- CFAP47 | c.2469G>A p.W823* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as rs867251085, COSV52890849; called by muse, mutect2, varscan2
- CFHR1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs1237921506, COSV57625702, COSV57628365; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CLVS1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs143211270, COSV57975512, COSV99073593; called by muse, mutect2, varscan2
- COL14A1 | c.4966C>T p.P1656S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52866351; called by muse, mutect2, varscan2
- CSMD2 | c.3260G>A p.W1087* | Nonsense Mutation (SNP) | VAF 61/221 reads (28%) | catalogued as COSV53955538; called by muse, mutect2, varscan2
- DACH1 | c.1822C>T p.P608S (on ENST00000619232 / NM_001366712.1; = p.P354S on NM_004392.6) | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs768301920, COSV57517541; called by muse, mutect2, varscan2
- DCLK1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1364916806, COSV55208443; called by muse, mutect2, varscan2
- DIP2C | c.2546A>G p.D849G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as COSV55176717; called by muse, mutect2, varscan2
- DMBT1 | c.6576T>A p.Y2192* (on ENST00000338354 / NM_001377530.1; = p.Y1435* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV57559123; called by muse, mutect2, varscan2
- DMXL1 | c.5716_5718del p.P1906del | In Frame Del (DEL) | VAF 29/92 reads (32%) | catalogued as rs765243696; called by mutect2, pindel, varscan2
- DNAH5 | c.3681T>G p.S1227R | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs755142785, COSV54248326; called by muse, mutect2, varscan2
- DNAH7 | c.10184C>T p.P3395L | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56758822; called by muse, mutect2, varscan2
- DNAH9 | c.8455G>A p.G2819R | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52344568; called by muse, mutect2
- DNAH9 | c.8456G>A p.G2819E | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99307599; called by muse, mutect2
- DTNA | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs768428161, COSV52023114, COSV52030880; called by muse, mutect2, varscan2
- DUSP16 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs759912271, COSV53809604; called by muse, mutect2, varscan2
- EDIL3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56918367, COSV99031181; called by muse, mutect2, varscan2
- EPHA7 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65170348; called by muse, mutect2, varscan2
- F5 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV63127757; called by muse, mutect2, varscan2
- FAM50B | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV66655187; called by muse, mutect2
- FBXO40 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV57527104; called by muse, mutect2, varscan2
- GDA | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760574784, COSV52991317; called by muse, mutect2, varscan2
- GLIS1 | c.603C>G p.D201E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV56555333; called by muse, mutect2, varscan2
- GRIP2 | c.799G>A p.G267R (on ENST00000619221; = p.G170R on NM_001080423.4) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs1270544792, COSV56124362; called by muse, mutect2, varscan2
- HCLS1 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100101035; called by muse, mutect2, varscan2
- IGHE | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1555457230; called by muse, mutect2, varscan2
- ITGAE | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs763227795, COSV53994324; called by mutect2, varscan2
- KCNC2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV54378296; called by muse, mutect2, varscan2
- KCNH5 | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59775315; called by muse, mutect2, varscan2
- KIAA1549 | c.5202G>A p.W1734* | Nonsense Mutation (SNP) | VAF 41/84 reads (49%) | catalogued as COSV54326497; called by muse, mutect2, varscan2
- KIAA2026 | c.3470C>T p.P1157L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1251347400, COSV101199183; called by muse, mutect2, varscan2
- KIAA2026 | c.3469C>A p.P1157T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV67356862; called by muse, mutect2, varscan2
- KLHL20 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV52941328; called by muse, mutect2, varscan2
- LCE1C | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64219148; called by muse, mutect2, varscan2
- LPA | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 115/394 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs369601677; called by muse, mutect2, varscan2
- LRP1B | c.7024C>T p.P2342S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67268006; called by muse, mutect2, varscan2
- LRRC19 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66259805; called by muse, mutect2, varscan2
- MEF2D | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.343); catalogued as COSV61730205; called by muse, mutect2, varscan2
- MMP27 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.055); catalogued as rs1266210302, COSV52782534; called by mutect2, varscan2
- NFE2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV56457179; called by muse, mutect2, varscan2
- NISCH | c.4421C>T p.P1474L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58742248; called by muse, mutect2
- NLRP1 | c.3449C>T p.P1150L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52577377; called by muse, mutect2, varscan2
- NMBR | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV57801954; called by muse, mutect2, varscan2
- NOMO1 | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1420968429, COSV99814820; called by mutect2, varscan2
- NRG1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55165550; called by muse, mutect2, varscan2
- NRK | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959576574, COSV54605392, COSV99688506; called by muse, mutect2, varscan2
- OR1F1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58960906; called by muse, mutect2, varscan2
- PCDH18 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV61271740; called by muse, mutect2, varscan2
- PCLO | c.11290C>T p.Q3764* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as COSV61620686; called by muse, mutect2, varscan2
- PDE1C | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV58517659, COSV58526606; called by muse, mutect2, varscan2
- PHF21B | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.259); catalogued as COSV57561702; called by muse, mutect2, varscan2
- PHKA1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59804362; called by muse, mutect2, varscan2
- PIK3C2A | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV56406523; called by muse, mutect2, varscan2
- PLA2G4C | c.1254C>G p.F418L | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs750061156, COSV62784527, COSV62787647; called by muse, mutect2, varscan2
- PLA2G6 | c.612C>T p.L204= | Splice Region (SNP) | VAF 19/56 reads (34%) | catalogued as COSV59269823; called by muse, mutect2, varscan2
- PLEKHG4B | c.620G>A p.G207E (on ENST00000283426; = p.G563E on NM_052909.5) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52054102; called by muse, mutect2, varscan2
- PLXNA4 | c.5573G>A p.G1858D | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.506); catalogued as rs1401868525, COSV58156235; called by muse, mutect2, varscan2
- PPP1R3A | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as COSV52891808; called by muse, mutect2, varscan2
- PRDM5 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs765109288, CM1512083, COSV53366646; called by muse, mutect2, varscan2
- PRMT1 | c.809C>G p.P270R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60196535, COSV60197653; called by muse, mutect2, varscan2
- PTK6 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs550929351, COSV53918356; called by muse, mutect2, varscan2
- RP1 | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1348070550, COSV55125258; called by muse, mutect2, varscan2
- RPRD2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs376972465; called by muse, mutect2, varscan2
- SCAMP5 | c.211T>G p.F71V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV62644090; called by muse, mutect2, varscan2
- SLC26A7 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV52603407; called by muse, mutect2, varscan2
- SLC44A4 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751632783, COSV57668646; called by muse, mutect2, varscan2
- SLC9A2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV52137123; called by muse, mutect2, varscan2
- SNAP91 | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1406103068, COSV52120012; called by muse, mutect2, varscan2
- SORCS3 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs556289294, COSV63795547, COSV63795826; called by muse, mutect2, varscan2
- SOX17 | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810796; called by muse, varscan2
- SYK | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65327359; called by muse, varscan2
- TBCEL | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.858); catalogued as rs267602731, COSV52458519, COSV52459005; called by mutect2, varscan2
- TEX13A | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.857); catalogued as rs1476768091, COSV61178873; called by muse, mutect2, varscan2
- TKTL2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54920967; called by muse, mutect2, varscan2
- TSPEAR | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59953697, COSV59968565; called by muse, varscan2
- TTN | c.49963C>T p.P16655S (on ENST00000591111; = p.P9231S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | PolyPhen probably damaging (0.998); catalogued as COSV60303505; called by muse, mutect2, varscan2
- USP31 | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as rs1278036659, COSV54856522; called by muse, mutect2, varscan2
- UTP25 | c.54A>T p.K18N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV72227507; called by muse, mutect2, varscan2
- VAV3 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV58391091; called by muse, mutect2, varscan2
- VCAM1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54121571; called by muse, mutect2, varscan2
- WDHD1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62215428; called by muse, mutect2, varscan2
- XDH | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs769203054, COSV65149486; called by muse, mutect2, varscan2
- ZNF208 | c.2635C>T p.H879Y | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68111823; called by muse, mutect2, varscan2
- ZNF233 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV61934608; called by muse, mutect2, varscan2
- ZNF384 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV60533022; called by muse, mutect2, varscan2
- ZNF439 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58310896, COSV58311238; called by muse, mutect2, varscan2
- EPHB2 | c.1966_1967del p.K656Vfs*90 (on ENST00000400191 / NM_001309193.2; = p.K657Vfs*90 on NM_004442.7) | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- HLA-DRB1 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- MRPL33 | c.64del p.S22Afs*20 | Frame Shift Del (DEL) | VAF 34/163 reads (21%) | called by mutect2, pindel, varscan2
- PCDH17 | c.2577dup p.P860Sfs*17 | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- PTPRG | c.615+1_615+2insA p.X205_splice | Splice Site (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- ABCG1 | c.525G>A p.Q175= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV59209762; called by muse, mutect2, varscan2
- ACP2 | c.990G>A p.R330= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV57040582; called by muse, mutect2, varscan2
- ADGRF5 | c.3441G>A p.L1147= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV51939312; called by muse, mutect2, varscan2
- ARID2 | c.699C>T p.F233= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs778247043, COSV57606085; called by muse, mutect2, varscan2
- BRD1 | c.2110C>T p.L704= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV53461086; called by muse, mutect2, varscan2
- C2CD3 | c.2295C>T p.L765= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs757665195, COSV58099867; called by muse, mutect2, varscan2
- CAMSAP3 | c.393C>T p.P131= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV50356381; called by muse, mutect2, varscan2
- CDAN1 | c.534C>T p.F178= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV51176033; called by muse, mutect2, varscan2
- CERCAM | c.633C>A p.P211= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV65711801; called by muse, mutect2, varscan2
- CHERP | c.2667T>A p.A889= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV52227427; called by muse, mutect2, varscan2
- CNOT6 | c.1014G>A p.S338= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs1475559179, COSV56163930; called by muse, mutect2, varscan2
- CSPG4 | c.1593C>T p.P531= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV57900552; called by muse, mutect2, varscan2
- DCTN1 | c.2172C>T p.I724= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs773948368, COSV62621384; called by muse, mutect2, varscan2
- DNAH9 | c.11013C>T p.A3671= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV52373846; called by muse, mutect2, varscan2
- DPPA2 | c.348C>T p.I116= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as rs749652172, COSV72118205, COSV72118241; called by muse, mutect2, varscan2
- EFHC2 | c.645C>T p.S215= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as rs768681960, COSV69555288; called by muse, mutect2, varscan2
- FAM214A | c.13C>A p.R5= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV55922921; called by muse, mutect2, varscan2
- FASLG | c.300G>A p.G100= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV60680882; called by muse, mutect2, varscan2
- FBXO10 | c.96C>T p.A32= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV52835304; called by muse, mutect2, varscan2
- GRM6 | c.2421C>T p.A807= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV51448900; called by muse, mutect2, varscan2
- HCLS1 | c.342G>A p.T114= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs1045342255, COSV58855778; called by muse, mutect2, varscan2
- HERC2 | c.10647G>T p.V3549= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV55346929; called by muse, mutect2, varscan2
- HIVEP1 | c.7086G>A p.K2362= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV65104634; called by muse, mutect2, varscan2
- HS3ST6 | c.615C>T p.R205= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs766740518, COSV53536655; called by muse, mutect2, varscan2
- IFNAR2 | c.216C>T p.I72= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV59751119; called by muse, mutect2, varscan2
- IGHV3-7 | c.13C>T p.L5= | Silent (SNP) | VAF 68/212 reads (32%) | called by muse, mutect2, varscan2
- IQCN | c.3060C>T p.F1020= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV62748654; called by muse, mutect2, varscan2
- KCNU1 | c.954G>A p.K318= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs1337901310, COSV67759420; called by muse, mutect2, varscan2
- KLK5 | c.627C>T p.I209= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV60451459; called by muse, mutect2, varscan2
- LEPR | c.2220C>T p.I740= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs757501135, COSV60750793; called by muse, mutect2, varscan2
- LIPI | c.351C>T p.F117= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs548960957, COSV60708768; called by muse, mutect2, varscan2
- MMRN1 | c.1836G>A p.E612= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV53334521, COSV53341876; called by muse, mutect2, varscan2
- NOMO1 | c.2799C>T p.F933= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as rs774718610, COSV99814818; called by muse, mutect2, varscan2
- NUP188 | c.3651G>A p.K1217= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV65364536; called by muse, mutect2
- OR11A1 | c.129G>A p.G43= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV65821343; called by muse, mutect2, varscan2
- OR1A1 | c.909C>T p.F303= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1567526316, COSV58404572; called by muse, mutect2, varscan2
- OR4Q3 | c.201T>G p.P67= | Silent (SNP) | VAF 34/237 reads (14%) | catalogued as COSV59180152; called by muse, mutect2, varscan2
- OR51Q1 | c.123C>T p.I41= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as rs267602953, COSV56180423; called by muse, mutect2, varscan2
- OR5B3 | c.168C>T p.P56= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV58676373, COSV58678530; called by muse, mutect2, varscan2
- P2RY10 | c.858C>T p.F286= | Silent (SNP) | VAF 100/148 reads (68%) | catalogued as COSV50685220; called by muse, mutect2, varscan2
- PARP4 | c.4648C>T p.L1550= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV67962684; called by muse, mutect2, varscan2
- PCDHB9 | c.390G>C p.S130= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV53383201; called by muse, mutect2
- PRSS16 | c.387G>A p.L129= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV57916734; called by muse, mutect2, varscan2
- RASSF3 | c.645C>T p.N215= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99309581; called by muse, mutect2, varscan2
- RASSF3 | c.646C>T p.L216= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV51683886; called by muse, mutect2, varscan2
- RPTOR | c.240C>T p.P80= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV60817026; called by muse, varscan2
- SH3RF2 | c.1875C>T p.I625= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV63041123; called by muse, mutect2, varscan2
- SI | c.4884C>T p.F1628= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100015606, COSV52277374; called by muse, mutect2, varscan2
- SIDT1 | c.468T>G p.G156= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV53506430; called by muse, mutect2, varscan2
- SLC22A9 | c.1638G>A p.P546= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs192219452; called by muse, mutect2, varscan2
- SLC2A7 | c.783G>A p.R261= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV68902333; called by muse, mutect2, varscan2
- SREK1 | c.1365T>C p.S455= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV52335005; called by muse, mutect2, varscan2
- TAS2R60 | c.180T>G p.V60= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV60331942; called by muse, mutect2, varscan2
- TLN1 | c.3190C>T p.L1064= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV59211328; called by muse, mutect2, varscan2
- TRIML1 | c.825G>A p.T275= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs541281684, COSV100206012, COSV60193746; called by muse, mutect2, varscan2
- TTN | c.15324G>A p.G5108= (on ENST00000591111; = p.G4181= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs772821743, COSV59952994, COSV60093995; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- TULP4 | c.3237C>T p.D1079= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV65580236; called by muse, mutect2, varscan2
- ZBTB7C | c.753C>T p.F251= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs766649382, COSV59688216; called by muse, mutect2, varscan2
- ZFAND2B | c.423C>T p.T141= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV54699775; called by muse, mutect2, varscan2
- C12orf77 | n.293C>T | RNA (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- COL6A2 | c.2461+2371G>A | Intron (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100153257, COSV56014118; called by muse, mutect2, varscan2
- FOCAD | c.57+731G>A | Intron (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100620654; called by muse, mutect2, varscan2
- HNF4G | c.-23-3815G>A | Intron (SNP) | VAF 57/111 reads (51%) | catalogued as rs374803306, COSV62970452; called by muse, mutect2, varscan2
- LGALS12 | c.*1G>A | 3'UTR (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99737304; called by muse, mutect2, varscan2
- TMEM183B | n.844G>A | RNA (SNP) | VAF 68/218 reads (31%) | catalogued as rs776679628; called by muse, mutect2, varscan2
